Surgical pathology report (de-identified scan), TCGA case TCGA-G2-A3VY, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site MD Anderson, specimen TCGA-G2-A3VY-01A (Primary Tumor).

DIAGNOSIS

(A) BLADDER TUMOR:
UROTHELIAL CARCINOMA, HIGH GRADE (GRADE 3), INVASIVE INTO
LAMINA PROPRIA AND STRONGLY SUSPICIOUS FOR FOCAL INVASION INTO
MUSCULARIS PROPRIA. (SEE COMMENT)

COMMENT

The tumor focally involves small bundles of smooth muscle tissue. Multiple additional deeper levels were examined. Although not definitive, the tumor is strongly suspicious for focal invasion into the muscularis propria. If clinically indicated, a rebiopsy may be considered for tumor staging.

T2 malignancy for second opinion - no treatment - same primary.

h

GROSS DESCRIPTION

(A) BLADDER TUMOR - Multiple fragments of tan-pink to gray-white, soft, rubbery tissue (2.5 x 2.2 x 0.5 cm) that is submitted entirely in A.

ICD-O-3
Carcinoma, urothelial, NOS
8120/3
Site: bladder, NOS
C67.9
6-712
RD

Case is Eligible	☒	☒
Reviewer Initials	M6	Date Reviewed: 4/13/12

Source: NCI Genomic Data Commons file 5c161254-fc0e-4cd7-a32d-3b7a19b84718 (TCGA-G2-A3VY.329F5DB7-9FC7-4856-8B15-1DBC9D6C42F6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).